Somatic mutation profile of tumor specimen 0DSA07 from CCDI case PBCHPI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.2 years (1,524 days).
Specimen 0DSA07: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e04d8b14-bfa7-46e0-9a77-1edc3f714c38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSA0S (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39815914-48f0-4d7b-8e5a-2a64253866e0

The open-access MAF lists 19 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 4, RNA 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GUCY2F | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV54305733; called by muse, mutect2, varscan2
- APOBR | c.2556G>T p.Q852H (on ENST00000431282; = p.Q861H on NM_018690.4) | Missense Mutation (SNP) | VAF 63/379 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MYH4 | c.806-12_806-2dup p.X269_splice | Splice Site (INS) | VAF 65/309 reads (21%) | called by mutect2, varscan2
- MYO19 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- PELP1 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- RTL3 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- TENM2 | c.890A>C p.E297A (on ENST00000518659 / NM_001122679.2; = p.E106A on NM_001080428.3) | Missense Mutation (SNP) | VAF 154/490 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TMTC2 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 34/641 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); called by muse, mutect2
- TOX3 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- AKT3 | c.888G>T p.G296= | Silent (SNP) | VAF 51/424 reads (12%) | called by muse, mutect2, varscan2
- GIPC2 | c.468C>A p.I156= | Silent (SNP) | VAF 78/335 reads (23%) | catalogued as rs774694759; called by muse, mutect2, varscan2
- PHGDH | c.16C>T p.L6= | Silent (SNP) | VAF 62/446 reads (14%) | catalogued as rs1557961852; called by muse, mutect2, varscan2
- SEC16B | c.2484G>A p.L828= | Silent (SNP) | VAF 55/221 reads (25%) | catalogued as rs1210911744; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+4039G>A | Intron (SNP) | VAF 53/459 reads (12%) | called by muse, mutect2, varscan2
- ATRX | c.-83G>T | 5'UTR (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- CACNA1C | c.6331-64G>A | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2
- KCNK10 | c.37+3592C>T | Intron (SNP) | VAF 22/149 reads (15%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85907G>A | Intron (SNP) | VAF 16/472 reads (3%) | called by muse, mutect2
- OR2W5 | n.1122G>A | RNA (SNP) | VAF 22/455 reads (5%) | called by muse, mutect2
